Somatic mutation profile of tumor specimen TCGA-HZ-8002-01A (aliquot TCGA-HZ-8002-01A-11D-2201-08) from TCGA case TCGA-HZ-8002, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 61.4 years (22,433 days).
Specimen TCGA-HZ-8002-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 047e78f5-ae05-4d63-aa8e-b89dcde44b94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-8002-10A (Blood Derived Normal), aliquot TCGA-HZ-8002-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72e6480e-0c5a-4ed6-a631-8188c0055b3d

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADARB2 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67238168; called by muse, mutect2
- NOL4 | c.1103G>C p.S368T | Missense Mutation (SNP) | VAF 28/1068 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.143); catalogued as COSV99308837; called by muse, mutect2
- PHF24 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 28/518 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs372732529; called by muse, mutect2
- RECQL5 | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 17/566 reads (3%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100512417; called by muse, mutect2
- TAGLN2 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 28/1060 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.323); catalogued as rs1319308244, COSV57423639; called by muse, mutect2
- TIMELESS | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 23/448 reads (5%) | SIFT tolerated (0.93); PolyPhen benign (0.122); catalogued as COSV99974432; called by muse, mutect2
- KCNA1 | c.1204C>T p.L402= | Silent (SNP) | VAF 148/2933 reads (5%) | catalogued as rs1565433504, COSV101230403, COSV101230405; called by muse, mutect2
- PLPPR4 | c.2172C>T p.R724= | Silent (SNP) | VAF 18/314 reads (6%) | catalogued as rs1465030099, COSV64564829; called by muse, mutect2
- ZFHX4 | c.7518A>G p.E2506= | Silent (SNP) | VAF 30/1059 reads (3%) | catalogued as COSV99268900; called by muse, mutect2
